Somatic mutation profile of tumor specimen 0DFRU9 from CCDI case PBBSRV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Angiomatoid fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 9.1 years (3,332 days).
Specimen 0DFRU9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0df30522-6ec7-4138-b2ce-61916fbd7e46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFRUA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10d12a34-1700-4fa2-9679-89f19f94bc95

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C16orf70 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 72/549 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs778233814; called by muse, mutect2, varscan2
- NCOR2 | c.6523C>T p.R2175C | Missense Mutation (SNP) | VAF 86/507 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs768792226; called by muse, mutect2, varscan2
- STXBP5L | c.3539A>G p.D1180G | Missense Mutation (SNP) | VAF 90/910 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- LAMB2 | c.3141G>A p.P1047= | Silent (SNP) | VAF 77/556 reads (14%) | catalogued as rs373002075; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLK5 | c.150G>A p.P50= | Silent (SNP) | VAF 57/423 reads (13%) | catalogued as rs1003605330; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 30/232 reads (13%) | called by muse, varscan2
